Surgical pathology report (de-identified scan), TCGA case TCGA-BB-7870, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-7870-01A (Primary Tumor).

[page 1 of 2]
SURG PATH REPORT

COLLECTION DATE/TIME:

1st Specimen collected on

FINAL DIAGNOSIS ----- Pathologist:

1. RIGHT PYRIFORM (RESECTION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.
2. INFERIOR MARGIN (RESECTION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.
3. RIGHT VALLECULAE (RESECTION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.
4. LEFT PYRIFORM (RESECTION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.
5. LEFT VALLECULAE (RESECTION): SQUAMOUS MUCOSA AND UNDERLYING LYMPHOID TISSUE, NEGATIVE FOR TUMOR.
6. TONGUE BASE (RESECTION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.
7. RIGHT NECK LEVEL 2 (RESECTION): SIXTEEN (16) LYMPH NODES WITH BENIGN LYMPHOID HYPERPLASIA, NEGATIVE FOR TUMOR. SEE NOTE.

NOTE: has reviewed a representative lymph node node from this section, and agrees with the diagnosis of benign lymphoid hyperplasia.

8. RIGHT NECK LEVEL 3 (RESECTION): EIGHT (8) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
9. RIGHT NECK LEVEL 4 (RESECTION): FIVE (5) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
10. LEFT NECK LEVEL 2 (RESECTION): TEN (10) LYMPH NODES WITH BENIGN LYMPHOID HYPERPLASIA, NEGATIVE FOR TUMOR. SEE NOTE.

NOTE: has reviewed a representative lymph node node from this section, and agrees with the diagnosis of benign lymphoid hyperplasia.

11. LEFT NECK LEVEL 3 (RESECTION): THIRTY-ONE (31) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
12. LEFT NECK LEVEL 4 (RESECTION): THIRTEEN (13) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
13. LARYNX (TOTAL LARYNGECTOMY):

SPECIMEN TYPE:

Resection (laryngectomy):

TUMOR SITE:

LARYNX:
Supraglottis.

TUMOR:

Greatest dimension 3.2.

HISTOLOGIC TYPE:

Squamous cell carcinoma, conventional.

HISTOLOGIC GRADE:

G3: Poorly differentiated.

PRIMARY TUMOR (pT): SUPRAGLOTTIS:

pT4a: Tumor invades through thyroid cartilage

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

[page 2 of 2]
REGIONAL LYMPH NODES (pN): ALL AERODIGESTIVE SITES EXCEPT
NASOPHARYNX.

pN0: No regional lymph node metastasis.

EXTRA-CAPSULAR EXTENSION OF NODAL TUMOR.
Absent.

DISTANT METASTASIS (pM):

pMx: Cannot be assessed.

MARGINS INVOLVED BY TUMOR:

Right lateral and right superior mucosal margins (specimen
margin). Left superior mucosal margin (specimen margin). For true
margin status please see Parts 1-6.

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:

Absent.

PERINEURAL INVASION:

Absent.

ADDITIONAL PATHOLOGIC FINDINGS:

Carcinoma in situ and chronic inflammation.

Attached fragment of benign thyroid tissue

NOTE: This case was shown at the daily Quality Assurance Conference.

Reported by:

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file 0ca794b9-7bd3-42ee-9578-4e95c5558bd4 (TCGA-BB-7870.3B8038FC-940B-4BDA-B275-6C8FCA428C9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).